Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A288, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A288-01A (Primary Tumor).

Path (First Tumor)

Tumor Site:	Cecum Proximal
Date of Cancer Sample Procurement:	
Histology:	Adenocarcinoma
Description of other histology:	
Grade:	Moderately Differentiated
Mucinous:	☐ No ☒ Yes ☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No ☐ Yes ☐ Unknown
Host Response:	Lymphoid Aggregates
Crohn's like reaction	☐ None ☒ Yes ☐ Unknown
Plasma cell rich stroma	☐ No ☐ Yes ☐ Unknown
Growth Pattern:	☒ Expansile ☐ Invasive ☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☐ No ☐ Yes ☒ Unknown
Angiolymphatic Invasion:	☒ No ☐ Yes ☐ Unknown
Mutator Phenotype:	☐ No ☒ Yes ☐ Unknown
Number of Slides	1
Garland Necrosis present:	☐ No ☒ Yes ☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	0
Pathologist Comment:	

1CD-0-3

adenocarcinoma, mucinous, NOS 8480/3

Site: Cecum C18.0

for 5/3/11

Source: NCI Genomic Data Commons file 19c8f8e8-c77e-4cc1-aed1-9a301a227032 (TCGA-DM-A288.EB32DBF8-FC70-4848-9595-45B295D698B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).